Somatic mutation profile of tumor specimen ALCH-B01S-TTP1-A (aliquot ALCH-B01S-TTP1-A-1-0-D-A657-36) from ALCHEMIST case ALCH-B01S, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 77.3 years (28,233 days).
Specimen ALCH-B01S-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6ebe532-f9e7-4bf8-8ef3-4b9ad47b3cc5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B01S-NB1-A (Blood Derived Normal), aliquot ALCH-B01S-NB1-A-1-0-D-A658-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f1f146b2-bded-4e4c-9e42-b2cbe73e7c9d

The open-access MAF lists 96 somatic variants for this specimen: 66 protein-altering or splice-affecting, 19 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 19, Intron 8, Nonsense Mutation 6, Frame Shift Del 4, Splice Site 2, 5'UTR 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 83/387 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 124/480 reads (26%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACTN3 | c.395G>T p.G132V | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101557855; called by muse, mutect2, varscan2
- BTBD16 | c.682A>T p.T228S | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.013); catalogued as COSV53260704; called by muse, mutect2, varscan2
- BTBD16 | c.683C>T p.T228I | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.122); catalogued as rs1564981281; called by muse, mutect2, varscan2
- CDCA2 | c.1700G>A p.G567E | Missense Mutation (SNP) | VAF 39/385 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.171); catalogued as COSV57944665; called by muse, mutect2, varscan2
- COL6A2 | c.2329T>A p.C777S | Missense Mutation (SNP) | VAF 30/233 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as CM050223, COSV55998575; called by muse, mutect2, varscan2
- CTC1 | c.1760A>G p.N587S | Missense Mutation (SNP) | VAF 82/289 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs376302717; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GABRG3 | c.47A>T p.H16L | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs1230356900; called by muse, mutect2
- GRP | c.217G>T p.E73* | Nonsense Mutation (SNP) | VAF 17/327 reads (5%) | catalogued as COSV56878978, COSV56880477; called by muse, mutect2
- JMJD1C | c.2339A>G p.H780R | Missense Mutation (SNP) | VAF 20/259 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.964); catalogued as rs940649961; called by muse, mutect2
- KLHL34 | c.1366G>C p.A456P | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.602); catalogued as COSV65279667; called by muse, mutect2, varscan2
- KRTAP5-2 | c.37G>A p.G13S | Missense Mutation (SNP) | VAF 9/116 reads (8%) | PolyPhen benign (0); catalogued as rs777393796; called by muse, mutect2
- LRP1B | c.11387G>A p.C3796Y | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as COSV101261754; called by muse, varscan2
- MARCHF1 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 28/209 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs926430693, COSV99922545; called by muse, mutect2, varscan2
- MED13 | c.1786C>T p.P596S | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.626); catalogued as rs529282192, COSV101181496; called by muse, mutect2
- MFAP1 | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 25/239 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.143); catalogued as rs1220683265; called by muse, mutect2
- NBEA | c.7297-1G>T p.X2433_splice | Splice Site (SNP) | VAF 9/47 reads (19%) | catalogued as COSV104403441, COSV59770142; called by muse, varscan2
- POTEF | c.56G>T p.G19V | Missense Mutation (SNP) | VAF 53/352 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs557666251; called by muse, mutect2, varscan2
- RPS6KA5 | c.1084G>T p.A362S | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV56221177; called by muse, mutect2, varscan2
- TOPORS | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs772307520; called by muse, mutect2, varscan2
- TRPV3 | c.1288C>T p.H430Y | Missense Mutation (SNP) | VAF 65/265 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs967353398; called by muse, mutect2, varscan2
- VEGFA | c.257G>A p.C86Y (on ENST00000523873 / NM_001171623.1; = p.C266Y on NM_003376.6) | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs374420337; called by muse, mutect2, varscan2
- VN1R4 | c.272G>T p.R91M | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100237359; called by muse, mutect2, varscan2
- ZNF22 | c.577A>G p.K193E | Missense Mutation (SNP) | VAF 10/274 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV53583971; called by muse, mutect2
- ANKS1B | c.1330G>T p.D444Y | Missense Mutation (SNP) | VAF 47/198 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- AOPEP | c.1438G>T p.E480* | Nonsense Mutation (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2, varscan2
- APOB | c.13002C>A p.N4334K | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C1GALT1 | c.56del p.G19Dfs*41 | Frame Shift Del (DEL) | VAF 41/315 reads (13%) | called by mutect2, pindel, varscan2
- DDX21 | c.1589G>C p.R530T | Missense Mutation (SNP) | VAF 38/310 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- EZH2 | c.1774G>A p.D592N (on ENST00000460911 / NM_001203247.2; = p.D597N on NM_004456.5) | Missense Mutation (SNP) | VAF 15/225 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.067); called by muse, mutect2
- F5 | c.2620C>T p.Q874* | Nonsense Mutation (SNP) | VAF 95/263 reads (36%) | called by muse, mutect2, varscan2
- FGD1 | c.2581G>C p.D861H | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FXR1 | c.1403-1G>A p.X468_splice | Splice Site (SNP) | VAF 31/196 reads (16%) | called by muse, mutect2
- GFRA1 | c.508T>A p.Y170N | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- GUCY2C | c.3076T>C p.F1026L | Missense Mutation (SNP) | VAF 38/210 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IFNA10 | c.400C>A p.L134M | Missense Mutation (SNP) | VAF 38/343 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, varscan2
- IGKV2D-26 | c.128G>T p.C43F | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- KBTBD8 | c.624C>A p.D208E | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- KLHL24 | c.1558G>T p.V520F | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- LRRIQ3 | c.1518A>C p.K506N | Missense Mutation (SNP) | VAF 14/343 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.198); called by muse, mutect2
- MYH6 | c.1757C>T p.T586I | Missense Mutation (SNP) | VAF 14/376 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.069); called by muse, mutect2
- MYO15A | c.8086G>C p.E2696Q | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, varscan2
- MYO15A | c.8122G>C p.V2708L | Missense Mutation (SNP) | VAF 55/502 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NAA30 | c.834G>T p.M278I | Missense Mutation (SNP) | VAF 35/550 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2
- NR0B1 | c.382C>A p.L128I | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- OR2T4 | c.1015G>A p.V339M | Missense Mutation (SNP) | VAF 28/342 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.043); called by muse, mutect2
- PHLPP1 | c.4203G>C p.K1401N | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLEC | c.3412A>T p.T1138S (on ENST00000322810 / NM_201380.4; = p.T1028S on NM_000445.5) | Missense Mutation (SNP) | VAF 9/176 reads (5%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2
- POLR1D | c.284C>A p.P95Q | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- PTPRZ1 | c.1056G>T p.Q352H | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.031); called by muse, mutect2
- RABAC1 | c.341_347del p.T114Sfs*11 | Frame Shift Del (DEL) | VAF 38/342 reads (11%) | called by mutect2, pindel
- RBMXL2 | c.857A>T p.Y286F | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- SGCD | c.505G>A p.E169K (on ENST00000435422 / NM_001128209.2; = p.E170K on NM_000337.5) | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.3); called by muse, mutect2
- SHISA7 | c.1508G>T p.R503L | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- SPTB | c.5416G>A p.G1806S | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2
- SRSF9 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by mutect2, varscan2
- SYNDIG1 | c.320C>A p.A107D | Missense Mutation (SNP) | VAF 42/296 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SYNE1 | c.3973G>T p.E1325* (on ENST00000367255 / NM_182961.4; = p.E1332* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 44/231 reads (19%) | called by muse, mutect2, varscan2
- TBC1D4 | c.3334G>A p.G1112R | Missense Mutation (SNP) | VAF 68/309 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- TMPRSS15 | c.771A>G p.I257M | Missense Mutation (SNP) | VAF 60/450 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- TRPC1 | c.1964A>G p.H655R (on ENST00000476941 / NM_001251845.2; = p.H621R on NM_003304.4) | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.966); called by muse, varscan2
- TYMP | c.388_391del p.A130Lfs*12 | Frame Shift Del (DEL) | VAF 34/288 reads (12%) | called by mutect2, pindel, varscan2
- UPF3B | c.109G>T p.E37* | Nonsense Mutation (SNP) | VAF 14/202 reads (7%) | called by muse, mutect2
- XCL1 | c.186del p.K63Nfs*4 | Frame Shift Del (DEL) | VAF 21/114 reads (18%) | called by mutect2, varscan2
- ZCCHC2 | c.280G>T p.E94* | Nonsense Mutation (SNP) | VAF 9/66 reads (14%) | called by muse, mutect2, varscan2
- ANKRD30BL | c.273G>A p.L91= | Silent (SNP) | VAF 10/121 reads (8%) | catalogued as rs1432079862; called by muse, mutect2
- ARHGAP39 | c.1185G>C p.V395= | Silent (SNP) | VAF 20/115 reads (17%) | called by muse, mutect2, varscan2
- CABS1 | c.843G>A p.R281= | Silent (SNP) | VAF 18/244 reads (7%) | called by muse, mutect2
- EPB41L1 | c.307C>T p.L103= | Silent (SNP) | VAF 67/492 reads (14%) | called by muse, mutect2, varscan2
- FGF13 | c.636C>A p.L212= | Silent (SNP) | VAF 8/136 reads (6%) | catalogued as COSV59545181; called by muse, mutect2
- FLNC | c.2700C>A p.A900= | Silent (SNP) | VAF 43/282 reads (15%) | called by muse, mutect2, varscan2
- HUWE1 | c.2106A>T p.P702= | Silent (SNP) | VAF 21/318 reads (7%) | catalogued as COSV99474060; called by muse, mutect2
- KCNH7 | c.3201C>A p.V1067= | Silent (SNP) | VAF 13/107 reads (12%) | catalogued as rs767809489, COSV59812486; called by muse, mutect2, varscan2
- NPR3 | c.1395A>G p.V465= | Silent (SNP) | VAF 26/259 reads (10%) | called by muse, mutect2
- OR2M3 | c.495C>A p.S165= | Silent (SNP) | VAF 12/224 reads (5%) | catalogued as COSV71759314; called by muse, mutect2
- PIGG | c.1212G>T p.L404= | Silent (SNP) | VAF 32/456 reads (7%) | catalogued as COSV99574478; called by muse, mutect2
- RET | c.342C>A p.R114= | Silent (SNP) | VAF 37/285 reads (13%) | catalogued as COSV100393794, COSV60686640; called by muse, mutect2, varscan2
- SERPINB3 | c.96C>A p.I32= | Silent (SNP) | VAF 26/316 reads (8%) | called by muse, mutect2
- STAT5B | c.2151T>C p.D717= | Silent (SNP) | VAF 20/121 reads (17%) | catalogued as rs1428602200; called by muse, mutect2, varscan2
- TMEM156 | c.570C>T p.Y190= | Silent (SNP) | VAF 20/294 reads (7%) | called by muse, mutect2
- TYRO3 | c.2073C>G p.A691= | Silent (SNP) | VAF 46/364 reads (13%) | called by muse, mutect2, varscan2
- VAV1 | c.2392C>A p.R798= | Silent (SNP) | VAF 37/276 reads (13%) | catalogued as COSV58386302; called by muse, mutect2, varscan2
- VPS8 | c.3555C>T p.A1185= (on ENST00000625842 / NM_001349294.1; = p.A1183= on NM_015303.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/154 reads (8%) | catalogued as rs1357186919; called by muse, mutect2
- ZNF28 | c.1641A>G p.A547= | Silent (SNP) | VAF 26/206 reads (13%) | called by muse, mutect2, varscan2
- AL109984.1 | n.186+4999G>A | Intron (SNP) | VAF 62/420 reads (15%) | catalogued as COSV63752104; called by muse, mutect2, varscan2
- CR1 | c.487+12112T>G | Intron (SNP) | VAF 73/453 reads (16%) | called by muse, mutect2, varscan2
- GRIN3A | c.-25C>T | 5'UTR (SNP) | VAF 23/144 reads (16%) | called by muse, mutect2, varscan2
- KRBOX4 | c.253+23G>T | Intron (SNP) | VAF 20/293 reads (7%) | called by muse, mutect2
- METTL14 | c.66+987T>A | Intron (SNP) | VAF 38/213 reads (18%) | called by muse, mutect2, varscan2
- MYH16 | n.2858A>G | RNA (SNP) | VAF 22/120 reads (18%) | called by muse, mutect2, varscan2
- NIBAN3 | c.1648-1457T>C | Intron (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2
- PRDM9 | c.-4C>A | 5'UTR (SNP) | VAF 32/366 reads (9%) | called by muse, mutect2
- RIMS2 | c.2084-942G>C | Intron (SNP) | VAF 12/264 reads (5%) | catalogued as rs910081914; called by muse, mutect2
- SLC17A4 | c.1121-27T>A | Intron (SNP) | VAF 44/186 reads (24%) | called by muse, mutect2, varscan2
- SYNE1 | c.9972+131A>G | Intron (SNP) | VAF 65/406 reads (16%) | catalogued as COSV99565110; called by muse, mutect2, varscan2
